Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAFG, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site Erasmus MC, specimen TCGA-2G-AAFG-01A (Primary Tumor).

ICD O-3
Seminoma NOS 9061/3
Site (R) Testis NOS C62.9
3/3/14

Concerning

Summary pathology report

Right orchidectomy; seminoma; diameter 4.7 cm; tumor confined to testis in available slides;
no angio-invasion; invasion in rete testis present.
s bilateral to

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

Source: NCI Genomic Data Commons file 566ca9c8-beec-4d31-91c9-5ab6d00e448c (TCGA-2G-AAFG.606A8F26-D2EF-4CF5-844A-3DE6DB389852.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).